Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25L, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25L-01A (Primary Tumor).

[page 1 of 2]
Diagnosis Discrepancy	Path cell	1st	No
HIF 1A Discrepancy			
Rec. date Initials	RB	Date Reviewed	4/27/11

FINAL DIAGNOSIS -----

1. THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

1CD-0-3

TUMOR SITE:

Left lobe

(Path)

Carcinoma, papillary, thyroid
8260/3

CQCF

Carcinoma, papillary, tall cell
8344/3

HISTOLOGIC TYPE:

Papillary carcinoma with focal tall cell features

Site: thyroid, NOS C73.9

TUMOR SIZE:

Greatest dimension: 3.0 cm

fw
6/2/11

FOCALITY:

Unifocal

LYMPH NODES:

Metastatic carcinoma in 2 of 12 nodes (includes all parts)

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Minimal extrathyroidal

extension into left inferior pole parathyroid gland

REGIONAL LYMPH NODES:

pN1b: Nodal metastasis to cervical nodes

MARGINS:

Involved by invasive carcinoma (posterior surgical margin)

VENOUS/LYMPHATIC INVASION:

Present

2. LEFT LEVEL III, IV, AND V (MODIFIED RADICAL NECK DISSECTION):

METASTATIC PAPILLARY THYROID CARCINOMA PRESENT IN ONE OF six (1 OF 6) LYMPH NODES (0.9 CM). EXTRANODAL EXTENSION IS PRESENT.

NOTE: The carcinoma involves an adjacent parathyroid gland (left inferior pole).

[page 2 of 2]
PART #1: TOTAL THYROID AND CENTRAL WEDGE DISSECTION

Dictated:

The specimen is received fresh labeled with the patient's name, xxxx and is designated 'total thyroid and central neck dissection'. The specimen has been previously oriented with a stitch marking the left tumor. The total thyroid weighs 18.7 gm and measures 7.0 x 5.5 x 2.9 cm. The left lobe measures 4.0 x 3.0 x 2.9 cm and the right lobe measures 4.0 x 3.0 x 1.4 cm. The anterior aspect of the specimen is inked orange, while the posterior aspect of is inked black. The specimen is serially sectioned to reveal a lesion in the left lobe measuring 3.0 x 2.0 x 2.0 cm that is harvested by the tissue bank. This mass has a homogeneous, yellow, firm, gelatinous cut surface and measurescut off. There is an attached portion of yellow, fibrofatty tissue along the left inferior thyroid pole which measures 3.0 x 1.0 x 0.6 cm. An attempt is made to search for lymph nodes. Three possible lymph nodes are identified.

SUMMARY OF SECTIONS

- 1 - A - 1 (RIGHT SUPERIOR LOBE)
- 1 - B - 1 (RIGHT MIDDLE LOBE)
- 1 - C - 1 (RIGHT INFERIOR LOBE)
- 1 - D - 1 (LEFT SUPERIOR LOBE)
- 1 - E - 1 (LEFT MIDDLE LOBE)
- 1 - F - 1 (LEFT INFERIOR LOBE)
- 1 - G - 1 (ISTHMUS)
- 2 - H,I - 1 EACH (TUMOR)
- 1 - J - 1 (TUMOR IN RELATION TO NORMAL)
- 1 - K - MULTIPLE (LN CANDIDATES)
- 1 - L - MULTIPLE (REMAINDER OF SOFT TISSUE)
- 12 - TOTAL - M

Source: NCI Genomic Data Commons file 00749713-387d-4bae-8b25-895c8a7deb1b (TCGA-ET-A25L.16B69890-694B-4489-BF48-F1EDC6776C29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).